Somatic mutation profile of tumor specimen MMRF_1970_1_BM_CD138pos (aliquot MMRF_1970_1_BM_CD138pos_T1_KBS5U_L07262) from MMRF case MMRF_1970, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.9 years (25,525 days).
Specimen MMRF_1970_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36ec2843-f69d-471a-85bc-4eda5024a1b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1970_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1970_1_PB_Whole_C2_KBS5U_L07263; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8158ff2-1464-41f3-90d5-1e2045d2e394

The open-access MAF lists 84 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 23, Silent 12, Intron 11, Frame Shift Del 2, 5'Flank 2, Splice Site 2, 5'UTR 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- LDLR | c.1706-1G>C p.X569_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as rs879254996, CS056759, CS159901, CS982251; ClinVar: pathogenic; called by muse, mutect2
- ABT1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV51290657; called by muse, mutect2, varscan2
- ADORA2A | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1368228423; called by muse, mutect2, varscan2
- CRACD | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.69); PolyPhen benign (0.073); catalogued as rs773571891, COSV51722784; called by muse, mutect2, varscan2
- IGHV2-70 | c.145A>T p.S49C | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs374002647; called by muse, varscan2
- IGHV2-70 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs374979633; called by muse, varscan2
- KCNK12 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as COSV59945489; called by muse, mutect2
- SERPINI2 | c.84A>T p.E28D | Missense Mutation (SNP) | VAF 96/332 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99247509; called by muse, mutect2, varscan2
- ADAMTSL5 | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ANKFY1 | c.2704C>G p.Q902E (on ENST00000341657 / NM_001330063.2; = p.Q903E on NM_016376.5) | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- BCL7A | c.28_36del p.T10_S12del | In Frame Del (DEL) | VAF 20/38 reads (53%) | called by mutect2, pindel, varscan2
- CD44 | c.2170T>C p.F724L | Missense Mutation (SNP) | VAF 154/412 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CEMIP2 | c.2616G>T p.Q872H | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DOCK1 | c.5552A>T p.K1851M | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- HHIP | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHD3-10 | c.12G>T p.W4C | Missense Mutation (SNP) | VAF 7/8 reads (88%) | called by muse, mutect2, varscan2
- MAD2L1BP | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.73); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR5H14 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PLEKHB2 | c.533G>A p.G178E (on ENST00000409279; = p.G177E on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXND1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SGK1 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- SLC12A7 | c.2708del p.R903Pfs*25 | Frame Shift Del (DEL) | VAF 35/78 reads (45%) | called by mutect2, pindel, varscan2
- SMG7 | c.2864G>A p.G955E | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SOGA3 | c.1477del p.M493* | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | called by mutect2, pindel, varscan2
- TACC2 | c.4628G>T p.G1543V | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TINAGL1 | c.489C>A p.S163R | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TMEM202 | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- URI1 | c.230T>G p.M77R | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- YEATS2 | c.1823G>C p.S608T | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YKT6 | c.288+2T>G p.X96_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- ZIM3 | c.467G>C p.G156A | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ZNF880 | c.395A>C p.K132T | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZNRF3 | c.1856G>C p.G619A (on ENST00000544604 / NM_001206998.2; = p.G519A on NM_032173.3) | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCB1 | c.1872A>G p.K624= | Silent (SNP) | VAF 52/146 reads (36%) | called by muse, mutect2, varscan2
- ALPP | c.393C>T p.T131= | Silent (SNP) | VAF 49/170 reads (29%) | catalogued as COSV101235129; called by muse, mutect2, varscan2
- APC | c.6024T>A p.A2008= | Silent (SNP) | VAF 72/167 reads (43%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.2238C>T p.D746= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs375648820, COSV62146656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECD | c.1383A>C p.I461= | Silent (SNP) | VAF 56/110 reads (51%) | called by muse, mutect2, varscan2
- GRIK2 | c.348C>T p.N116= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs201788540, COSV59771289; called by muse, mutect2, varscan2
- IGHV2-70 | c.252G>T p.L84= | Silent (SNP) | VAF 56/108 reads (52%) | catalogued as rs374732396; called by muse, varscan2
- KMT2D | c.712T>C p.L238= | Silent (SNP) | VAF 48/101 reads (48%) | called by muse, mutect2, varscan2
- LONRF2 | c.1185C>T p.P395= | Silent (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- PARD6B | c.426G>T p.V142= | Silent (SNP) | VAF 86/172 reads (50%) | called by muse, mutect2, varscan2
- TACC2 | c.2310G>A p.S770= | Silent (SNP) | VAF 57/108 reads (53%) | catalogued as rs747341872, COSV100552487; called by muse, mutect2, varscan2
- TSHZ3 | c.720C>T p.R240= | Silent (SNP) | VAF 148/467 reads (32%) | catalogued as rs760381593; called by muse, mutect2, varscan2
- ACAA2 | chr18:49813824 A>G | 5'Flank (SNP) | VAF 142/349 reads (41%) | called by muse, mutect2, varscan2
- ADCY1 | c.*1798C>T | 3'UTR (SNP) | VAF 29/104 reads (28%) | catalogued as rs1392367717; called by muse, mutect2, varscan2
- ARPC5 | c.216+40C>T | Intron (SNP) | VAF 61/119 reads (51%) | called by muse, mutect2, varscan2
- BAG5 | c.-29+335G>A | Intron (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- COL6A5 | c.7820-76A>T | Intron (SNP) | VAF 120/410 reads (29%) | called by muse, varscan2
- COL6A5 | c.7820-75T>A | Intron (SNP) | VAF 114/405 reads (28%) | called by muse, varscan2
- CXCL2 | c.308+43del | Intron (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- DPYSL3 | c.*625T>A | 3'UTR (SNP) | VAF 54/112 reads (48%) | called by muse, mutect2, varscan2
- DUSP28 | c.*183A>G | 3'UTR (SNP) | VAF 51/125 reads (41%) | called by muse, mutect2, varscan2
- DYNC2LI1 | c.321-1201_321-1194del | Intron (DEL) | VAF 26/31 reads (84%) | called by mutect2, pindel, varscan2
- EFCAB2 | c.*1290A>G | 3'UTR (SNP) | VAF 37/80 reads (46%) | catalogued as rs908949680; called by muse, mutect2, varscan2
- EFR3B | c.2143-2213C>G | Intron (SNP) | VAF 44/147 reads (30%) | called by muse, mutect2, varscan2
- EFR3B | c.2143-1861C>G | Intron (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- FNIP2 | c.*2445C>G | 3'UTR (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- FSTL4 | c.*1070C>A | 3'UTR (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- GAPVD1 | c.*1393A>C | 3'UTR (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- GATA5 | c.*153C>T | 3'UTR (SNP) | VAF 38/73 reads (52%) | catalogued as rs879959351; called by muse, mutect2, varscan2
- IGLL5 | c.-11C>T | 5'UTR (SNP) | VAF 35/71 reads (49%) | catalogued as rs528299670, COSV73249616, COSV73251126; called by muse, mutect2, varscan2
- IGLL5 | c.-10C>G | 5'UTR (SNP) | VAF 36/72 reads (50%) | catalogued as rs551248126, COSV104440277; called by muse, mutect2, varscan2
- LHFPL2 | c.*1201C>T | 3'UTR (SNP) | VAF 47/96 reads (49%) | called by muse, mutect2, varscan2
- MEIS1 | c.240-374C>G | Intron (SNP) | VAF 27/253 reads (11%) | called by muse, mutect2, varscan2
- METTL2A | c.*2194A>C | 3'UTR (SNP) | VAF 47/88 reads (53%) | called by muse, mutect2, varscan2
- RIC8A | c.*284G>A | 3'UTR (SNP) | VAF 122/171 reads (71%) | called by muse, mutect2, varscan2
- SEC22C | c.*3681G>C | 3'UTR (SNP) | VAF 71/214 reads (33%) | called by muse, mutect2, varscan2
- SGK1 | chr6:134175871 C>G | 5'Flank (SNP) | VAF 18/37 reads (49%) | catalogued as COSV52808614; called by muse, mutect2, varscan2
- SLC5A7 | c.*1846C>A | 3'UTR (SNP) | VAF 7/103 reads (7%) | called by muse, mutect2
- SMU1 | c.*3205T>C | 3'UTR (SNP) | VAF 54/172 reads (31%) | called by muse, mutect2, varscan2
- SOX6 | c.-5+88C>T | Intron (SNP) | VAF 231/681 reads (34%) | called by muse, mutect2, varscan2
- ST3GAL1 | c.*3610A>C | 3'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- STC1 | c.*1476A>T | 3'UTR (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- STPG2 | c.*29C>A | 3'UTR (SNP) | VAF 101/199 reads (51%) | catalogued as COSV99760903; called by mutect2, varscan2
- SYNGAP1 | c.296-404G>C | Intron (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- TMEM30B | c.*242C>T | 3'UTR (SNP) | VAF 46/104 reads (44%) | catalogued as rs779256729; called by muse, mutect2, varscan2
- TMSB4X | c.*217C>G | 3'UTR (SNP) | VAF 52/54 reads (96%) | catalogued as COSV66081642; called by muse, mutect2, varscan2
- TNFRSF19 | c.*968G>A | 3'UTR (SNP) | VAF 40/72 reads (56%) | catalogued as rs566750028, COSV50320305; called by muse, mutect2, varscan2
- TYW1B | c.*357del | 3'UTR (DEL) | VAF 94/279 reads (34%) | called by mutect2, varscan2
- XKR4 | c.*1400C>T | 3'UTR (SNP) | VAF 27/62 reads (44%) | catalogued as rs1563373734; called by muse, mutect2, varscan2
- ZBTB46 | c.*1581del | 3'UTR (DEL) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
